Somatic mutation profile of tumor specimen TCGA-XF-A9SW-01A (aliquot TCGA-XF-A9SW-01A-11D-A42E-08) from TCGA case TCGA-XF-A9SW, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 85.0 years (31,049 days).
Specimen TCGA-XF-A9SW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fcb226b7-0cdf-4a6d-b13a-17da6be800ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9SW-10A (Blood Derived Normal), aliquot TCGA-XF-A9SW-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b77511f7-cdb6-432c-9044-d71efbeccb4c

The open-access MAF lists 64 somatic variants for this specimen: 41 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 22, Splice Site 2, Frame Shift Del 1, Intron 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS10 | c.2441G>T p.R814L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV54353135, COSV99547397; called by muse, mutect2, varscan2
- AFAP1 | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV61794598; called by muse, mutect2, varscan2
- AZIN2 | c.1054T>C p.Y352H | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as COSV53856634; called by muse, mutect2, varscan2
- CCNE2 | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57375387; called by muse, mutect2, varscan2
- CEL | c.1378G>A p.D460N (on ENST00000673714; = p.D457N on NM_001807.6) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs745498383, COSV60826641, COSV60828243; called by muse, mutect2, varscan2
- CHODL | c.770C>G p.S257C | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs777392789, COSV53037393; called by muse, mutect2, varscan2
- COL5A3 | c.4357C>T p.P1453S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as rs1429863551, COSV53408423; called by muse, mutect2, varscan2
- CYTH3 | c.698A>T p.E233V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as COSV63438117; called by muse, mutect2
- DNAH6 | c.1933T>G p.F645V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV52854617; called by muse, mutect2, varscan2
- FCGR2A | c.629T>C p.M210T (on ENST00000271450 / NM_001136219.3; = p.M209T on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1179504708, COSV54837769; called by muse, mutect2, varscan2
- FILIP1 | c.3398C>T p.P1133L | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs763126633, COSV52726023; called by muse, mutect2, varscan2
- FOXN3 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54306426; called by muse, mutect2, varscan2
- GPR162 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50589863; called by muse, mutect2, varscan2
- HIPK2 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100702648; called by muse, mutect2
- MELTF | c.1454G>A p.G485D | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750961407, COSV56380265; called by muse, mutect2, varscan2
- MRM2 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV54247805; called by muse, mutect2, varscan2
- MYCT1 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV65891143; called by muse, mutect2, varscan2
- NAV1 | c.1781C>T p.S594L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422341119, COSV55215595; called by muse, mutect2, varscan2
- PCLO | c.10589C>A p.P3530Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV61614241, COSV61624784; called by muse, mutect2, varscan2
- PLXNB2 | c.4486G>C p.D1496H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63780775, COSV63781547; called by muse, mutect2, varscan2
- PODXL | c.1492G>C p.E498Q (on ENST00000378555 / NM_001018111.3; = p.E466Q on NM_005397.4) | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59869421; called by muse, mutect2, varscan2
- PPIL4 | c.1255C>T p.H419Y | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.068); catalogued as COSV53566790; called by muse, mutect2, varscan2
- PRRC2C | c.3488A>C p.K1163T (on ENST00000367742; = p.K1161T on NM_015172.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV58903105; called by muse, mutect2
- PTPRM | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59851472; called by muse, mutect2, varscan2
- PTPRZ1 | c.3278C>T p.S1093F | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66433661; called by muse, mutect2, varscan2
- RALGAPB | c.4291+1G>A p.X1431_splice | Splice Site (SNP) | VAF 17/122 reads (14%) | catalogued as COSV53436095; called by muse, mutect2, varscan2
- RB1 | c.1901C>A p.S634* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as CM961233, COSV57296525, COSV57302654; called by muse, mutect2, varscan2
- SAMD9L | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV59080559; called by muse, mutect2, varscan2
- SEPTIN14 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.184); catalogued as COSV66426825, COSV66426978; called by muse, mutect2, varscan2
- SPARC | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs150910656; called by muse, mutect2, varscan2
- SPRR1B | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.867); catalogued as COSV61067520; called by muse, mutect2, varscan2
- STK38L | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.014); catalogued as COSV66520993; called by muse, mutect2, varscan2
- STON1 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100562417, COSV59128384; called by muse, mutect2, varscan2
- STRIP2 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759758349, COSV50804585, COSV99973446; called by mutect2, varscan2
- TAF11 | c.408+2T>C p.X136_splice | Splice Site (SNP) | VAF 15/97 reads (15%) | catalogued as COSV51954151; called by muse, mutect2, varscan2
- TRIM37 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99232454; called by muse, mutect2
- WDR31 | c.568G>A p.V190M (on ENST00000374193 / NM_001006615.3; = p.V189M on NM_145241.5) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs765900217, COSV59145708; called by mutect2, varscan2
- ZSWIM4 | c.2704G>A p.A902T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99585542; called by muse, mutect2
- ARID1A | c.6700del p.A2234Lfs*33 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- FRG2 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PPIG | c.289+1_289+3dup | Splice Region (INS) | VAF 26/114 reads (23%) | called by mutect2, pindel, varscan2
- ADGRD1 | c.1038G>A p.V346= | Silent (SNP) | VAF 56/168 reads (33%) | catalogued as COSV55441890; called by muse, mutect2, varscan2
- CD163 | c.735G>A p.K245= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs749798626, COSV63130796; called by muse, mutect2, varscan2
- CHDH | c.786G>A p.V262= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs558882361, COSV100179929; called by muse, mutect2
- FCN1 | c.924G>A p.A308= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs373784301; called by muse, mutect2
- GAD2 | c.1449C>T p.N483= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs1012884220, COSV52154097; called by muse, mutect2, varscan2
- IDO2 | c.753G>T p.L251= (on ENST00000389060; = p.L264= on NM_194294.2) | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs1321381062, COSV58424628; called by muse, mutect2, varscan2
- KRT1 | c.1785C>T p.G595= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99359041; called by muse, mutect2
- LAMA5 | c.4359C>T p.F1453= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs778382767, COSV53356454; called by muse, mutect2, varscan2
- MAP3K5 | c.2790C>T p.N930= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs1303233596, COSV62888210; called by muse, mutect2, varscan2
- MRNIP | c.175T>C p.L59= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV52972574; called by muse, mutect2, varscan2
- NEK6 | c.666C>T p.N222= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as rs777505101, COSV57216695; called by muse, mutect2
- NXF3 | c.1461C>T p.I487= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs757991501, COSV67703121; called by muse, mutect2, varscan2
- PCDH9 | c.2844T>C p.F948= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV60538475; called by muse, mutect2, varscan2
- PKD1L1 | c.922C>T p.L308= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as COSV56961460; called by muse, mutect2, varscan2
- PPFIA3 | c.1038G>A p.K346= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV61950637; called by muse, mutect2, varscan2
- PRELID2 | c.336T>G p.L112= (on ENST00000334744 / NM_182960.4; = p.L71= on NM_138492.6) | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV58278927; called by muse, mutect2, varscan2
- QARS1 | c.1857C>T p.F619= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV60274474; called by muse, mutect2, varscan2
- SHCBP1 | c.31C>T p.L11= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV57646815; called by muse, mutect2, varscan2
- SLC51A | c.540G>A p.L180= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as COSV56351237; called by muse, mutect2, varscan2
- SPATS1 | c.654C>T p.F218= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV55822452; called by muse, mutect2, varscan2
- TRAF3 | c.234G>A p.A78= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs916514561, COSV61024413; called by muse, mutect2, varscan2
- TRAV39 | c.69A>G p.E23= | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- PPP1R8 | c.117+1704C>G | Intron (SNP) | VAF 37/92 reads (40%) | catalogued as COSV52580591, COSV99361151; called by muse, mutect2, varscan2
